Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A76L, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A76L-01A (Primary Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology Document State: (version)
Update Date/Time:
Final I

Patient Name: MRN: Service Date/Time:
DOB/Age/Gender: Male Provider:
Location: Responsible Staff:

PATH.NO:
NAME: MED. REC. NO:
AGE/SEX: M DOB: SURGERY DATE:
RECEIVE DATE:
PHYSICIAN:
COPY TO:

PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, RIGHT TEMPORAL, EXCISION: ANAPLASTIC OLIGODENDROGLIOMA.
GRADE IV/IV. MIB-1 LABELLING INDEX 37%.
SEE MICROSCOPIC DESCRIPTION AND COMMENT.

Operation/Specimen: Craniotomy, temporal lobe.

Clinical History and Pre-Op Dx: year old man with right temporal lobe tumor.

GROSS PATHOLOGY: Received fresh, two fragments, 1.1 cm. across, in aggregate. Soft, focally hemorrhagic and glistening. In total #1 and 2.

INTRAOPERATIVE CONSULTATION: Brain, right temporal: Glioma, high histological grade.

B.

SPECIMEN: Right temporal tumor - permanent.

FIXATIVE: Saline.

GENERAL: A 2.0 x 1.8 x 0.2 cm. aggregate of numerous, fragmented tan-red soft tissue fragments and scanty blood clot.

SECTIONS: X1,X2 - all submitted.

MICROSCOPIC: A. Portions of cerebrum effaced by a neoplastic proliferation of glial cells. The neoplasm is very cellular and made up of round or ovoid neoplastic nuclei with anaplastic features. The background is fibrillary and has prominent microvascular cellular proliferation. Mitotic figures are very frequent. There is individual cell necrosis and areas of geographic tumor necrosis. At the periphery of the tumor, neoplastic cells have perinuclear halos suggestive of an oligodendroglial nature.

B. Portions of brain with a neoplasm similar to that one described for part A. However, in this specimen there are zones of clearly identifiable anaplastic oligodendroglioma, and extensive areas of necrosis.

SPECIAL STAINS: Immunoperoxidase methods for GFAP and MIB-1 were performed on block #2. The GFAP demonstrates a moderately fibrillary background, and highlights the prominent microvascular cellular proliferation. With the MIB-1 a labelling index of 37% is determined.

COMMENT: In this material there is a high histological grade glioma that in less anaplastic areas has an oligodendroglial phenotype. The neoplasm has prominent nuclear anaplasia, mitotic activity, microvascular cellular proliferation, and areas of tumor necrosis, namely a WHO grade IV/IV glioma. This tumor may also be diagnosed as a glioblastoma multiforme with an oligodendroglial component. The proliferation index is 37%.

ICD6-3

Oligodendroglioma, grade III
9451/3

Site C6CF

Brain, supratentorial NOS
C71.0

Left Brain, temporal lobe
C71.2

gtw 9/30/13

[page 2 of 2]
TISSUE COMMITTEE CODE: TC1.
BILLING CODES:

Source: NCI Genomic Data Commons file ba9e4ebd-9ea9-4984-9991-57dd85538a16 (TCGA-DU-A76L.E66BD7A0-E6D5-4773-9718-154F4D4253A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).